Gene-level copy-number profile of tumor specimen TCGA-G4-6295-01A from TCGA case TCGA-G4-6295, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cecum; AJCC pathologic stage: Stage II; Age at diagnosis: 70.5 years (25,758 days).
Specimen TCGA-G4-6295-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.f26d42ea-1349-4b3f-8554-7d77494db78f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G4-6295-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2544d2bc-a3ed-406e-b5c9-1b08f1ee834b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 44; copy number 1: 5,276; copy number 2: 25,525; copy number 3: 20,814; copy number 4: 5,386; copy number 5: 41; copy number 7: 1,619; copy number 8: 1,114.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-G4-6295-01A-11D-1717-01): tumor purity 0.69, ploidy 2.79, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 44 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:3,377,527–3,513,852, 8 genes (within-gene range 0–1): OR1AC1P, OR1R1P, OR1E1, OR3A3, OR1E2, AC025125.1, SPATA22, ASPA.
- chr17:15,786,618–16,492,193, 32 genes: MEIS3P1, AC015922.2, AC015922.3, AC015922.1, LINC02087, SPECC1P1, ADORA2B, ZSWIM7, TTC19, AC002553.2, NCOR1, AC002553.1, RPLP1P11, RPL22P21, RNU6-314P, RNU6-862P, RN7SL442P, PIGL, MIR1288, CENPV, UBB, AC093484.3, FTLP12, AC093484.2, TRPV2, AC093484.1, SNHG29, SNORD49B, SNORD49A, AC093484.4, SNORD65, LRRC75A.
- chr17:27,874,645–27,991,787, 4 genes: AC005697.2, LYRM9, LINC01992, AC005697.3.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,774 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:76,185,020–76,399,490, 1 gene, copy number 5 (within-gene range 4–5): AC073091.1.
- chr2:76,258,034–80,648,861, 40 genes, copy number 5 (within-gene range 4–5): PNPP1, USP21P2, RN7SKP203, RN7SKP164, AC068616.2, AC068616.3, AC068616.1, LRRTM4, RNA5SP98, AC079117.1, LRRTM4-AS1, AC013716.1, AC012494.1, AC084149.1, RPL38P2, LINC01851, AC012494.2, CYCSP6, AC064872.1, AC092660.1, AC092604.1, RNU6-827P, RNU6-812P, REG3G, REG1B, REG1A, REG1CP, REG3A, AC011754.1, CTNNA2, AC011754.2, CTNNA2-AS1, AC010975.1, GNA13P1, RNU6-561P, MIR4264, MIR8080, AC016716.1, RBM7P1, LRRTM1.
- chr8:30,831,544–30,921,335, 2 genes, copy number 7 (within-gene range 1–7): TEX15, AC090281.1.
- chr8:39,743,735–145,066,685, 1,633 genes, copy number 7–8 (within-gene range 1–8) (broad region; genes not listed).
- chr20:17,887,363–18,569,563, 32 genes, copy number 8: AL035045.1, RNU6-192P, SNX5, OVOL2, SNORD17, MGME1, PTMAP3, AL160411.1, RPL15P1, RNU7-137P, Y_RNA, KAT14, PET117, GGCTP2, RN7SL14P, RNU2-56P, AL049646.2, ZNF133, AL049646.1, RN7SKP74, ZNF133-AS1, LINC00851, DZANK1, GCNT1P1, RNA5SP476, POLR3F, MIR3192, RPL21P3, RBBP9, RPS19P1, SEC23B, SMIM26.
- chr20:18,592,330–18,611,167, 2 genes, copy number 8: RN7SL638P, RNU6ATAC34P.
- chr20:20,970,448–64,313,132, 1,064 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,855. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
